Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A3DO, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A3DO-01A (Primary Tumor).

	Yes	No
IIHAA Discrepancy		☒

SPECIMEN TAKEN:

FINAL DIAGNOSIS -----

TOTAL THYROIDECTOMY:

SPECIMEN TYPE: Total thyroidectomy

TUMOR SITE: Right lobe (main mass) and left lobe

HISTOLOGIC TYPE: Papillary carcinoma

1CD-0-3

TUMOR SIZE: Greatest dimension: 2.5 cm

Carcinoma, papillary, thyroid

FOCALITY: Multifocal

8260/3

Site: thyroid, nos C13.9

LYMPH NODES: None submitted

EXTENT OF INVASION

PRIMARY TUMOR:

pT2: Tumor >2cm but <4 cm, limited to thyroid

hw
10/24/11

REGIONAL LYMPH NODES:

pNX: Cannot be assessed

DISTANT METASTASIS:

pMX: Cannot be assessed

MARGINS: Margins are uninvolved

Distance of invasive carcinoma from nearest margin: 1 mm (soft tissue margin)

VENOUS/LYMPHATIC INVASION:

Not identified

ADDITIONAL PATHOLOGIC FINDINGS:

Lymphocytic thyroiditis

Note: The largest focus of tumor (2.5 cm) involves the right lobe. A separate focus of papillary carcinoma (0.4 cm) is located in the left lobe. This case was shown at the

Source: NCI Genomic Data Commons file c625114c-b1a1-4ba0-b53d-8f8965eb0994 (TCGA-ET-A3DO.25667964-D12A-43A9-8B5E-DDBFDB694D74.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).